TARGET case TARGET-10-PANSTB — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/2683eae9-80f3-5295-a89f-36421bb03708

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 1,063 days (2.9 years).

Diagnoses (1)
1. Precursor B-cell lymphoblastic leukemia: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 3.9 years (1,440 days); Year of diagnosis: 2005; Days to last follow up: 1,063 days (2.9 years).

Biospecimens (2 samples)
- Sample TARGET-10-PANSTB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PANSTB-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
